Somatic mutation profile of tumor specimen TCGA-06-0648-01A (aliquot TCGA-06-0648-01A-01D-1492-08) from TCGA case TCGA-06-0648, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.0 years (28,477 days).
Specimen TCGA-06-0648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a89ed8a7-df65-40e5-961c-e59b8d144054.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0648-10A (Blood Derived Normal), aliquot TCGA-06-0648-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a15ce9c-18d5-479f-b0d7-ad313c68741f

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 39, Silent 16, Nonsense Mutation 4, Frame Shift Del 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 92/159 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV53052758; called by muse, mutect2, varscan2
- ADGRD1 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55440410; called by muse, mutect2, varscan2
- AHNAK2 | c.10942T>C p.F3648L | Missense Mutation (SNP) | VAF 139/358 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV60916428; called by muse, mutect2, varscan2
- ANO1 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60285043; called by muse, mutect2, varscan2
- ANO5 | c.160T>G p.F54V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV61085320; called by muse, mutect2, varscan2
- ANP32E | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58482315; called by muse, mutect2, varscan2
- ATP6V1G1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1393915080, COSV65014128; called by muse, mutect2, varscan2
- BCAM | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs750550926, COSV54301352; called by muse, mutect2, varscan2
- CABIN1 | c.3673G>A p.V1225I | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as rs528073328, COSV54082295; called by muse, mutect2, varscan2
- CANX | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 226/550 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs753869333, COSV56004337; called by muse, mutect2, varscan2
- CCDC60 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs761390907, COSV59544403; called by muse, mutect2
- CEACAM7 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs369677539; called by muse, mutect2, varscan2
- COL27A1 | c.5236C>T p.R1746W | Missense Mutation (SNP) | VAF 139/352 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763342715, COSV61926512; called by muse, varscan2
- CXCL6 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs149811429; called by muse, mutect2, varscan2
- DBT | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as rs533707792, COSV64495530; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMXL1 | c.5373A>G p.I1791M | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60712418; called by muse, mutect2
- DNAH2 | c.13097G>A p.R4366Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs145226741, COSV66716440; called by muse, mutect2, varscan2
- FOXR2 | c.782A>C p.D261A | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59258522; called by muse, mutect2, varscan2
- FPR2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as rs192933693, COSV60672310; called by muse, mutect2, varscan2
- KSR2 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.889); catalogued as COSV56668409; called by muse, mutect2, varscan2
- LGALS13 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | catalogued as rs534285827, COSV55680035; called by muse, mutect2, varscan2
- MCM4 | c.2503A>G p.I835V | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs747765310, COSV50623927; called by muse, mutect2, varscan2
- NPNT | c.840C>A p.D280E | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.08); catalogued as COSV59754052; called by muse, mutect2
- OR4D2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV73459770; called by muse, mutect2, varscan2
- OR5D16 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV65722091; called by muse, mutect2, varscan2
- PAAF1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1185994727, COSV60155681; called by muse, mutect2, varscan2
- PCDH7 | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); catalogued as COSV62339367; called by muse, mutect2, varscan2
- RRAGA | c.867_868insTTG p.N289_I290insL | In Frame Ins (INS) | VAF 91/264 reads (34%) | catalogued as COSV100998180; called by mutect2, pindel, varscan2
- RRP1B | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as COSV61479163; called by muse, mutect2, varscan2
- SCFD1 | c.914C>G p.A305G | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV61724151; called by muse, mutect2
- SERPINA6 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs747671539, COSV58585130; called by muse, mutect2, varscan2
- SHOX | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61860941; called by muse, mutect2, varscan2
- SLC29A4 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs1307878354, COSV51874462; called by muse, mutect2, varscan2
- SLIT3 | c.3520G>A p.A1174T | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs200822063, COSV60593379; called by muse, mutect2, varscan2
- SMYD2 | c.1032C>A p.Y344* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV65290952; called by muse, mutect2, varscan2
- STK31 | c.2644C>T p.R882* | Nonsense Mutation (SNP) | VAF 9/210 reads (4%) | catalogued as COSV63456300, COSV63457557; called by muse, mutect2
- SYNM | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.211); catalogued as rs782617752, COSV60370747; called by muse, mutect2, varscan2
- TENM3 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs899237384, COSV69309153; called by muse, varscan2
- TENM3 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69309158; called by muse, varscan2
- TMEM241 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67244076; called by muse, mutect2, varscan2
- TTN | c.30740C>A p.P10247H (on ENST00000591111; = p.P9320H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | PolyPhen probably damaging (0.999); catalogued as COSV60087750; called by muse, mutect2, varscan2
- TTN | c.28592G>A p.R9531Q (on ENST00000591111; = p.R8604Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/161 reads (40%) | PolyPhen probably damaging (0.996); catalogued as rs773444238, CM094356, COSV60087764; called by muse, mutect2, varscan2
- ZNF417 | c.280T>G p.C94G | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV56309331; called by muse, mutect2, varscan2
- ABCF1 | c.1204del p.E402Nfs*11 (on ENST00000326195 / NM_001025091.2; = p.E364Nfs*11 on NM_001090.3) | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | called by mutect2, pindel, varscan2
- FBXO22 | c.336del p.S113Vfs*37 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- C12orf66 | c.561C>T p.F187= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV61323283; called by muse, mutect2, varscan2
- DCLK1 | c.990G>A p.S330= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs200783749, COSV55171920; called by muse, mutect2
- DUOX2 | c.3162C>T p.G1054= | Silent (SNP) | VAF 52/67 reads (78%) | catalogued as rs372592162; called by muse, mutect2, varscan2
- FAT1 | c.3831C>T p.T1277= | Silent (SNP) | VAF 208/534 reads (39%) | catalogued as rs553222395, COSV71672074; called by muse, mutect2, varscan2
- FGD5 | c.1857C>T p.F619= | Silent (SNP) | VAF 62/129 reads (48%) | catalogued as rs771459242, COSV53243569; called by muse, mutect2, varscan2
- GCSAM | c.402T>C p.P134= | Silent (SNP) | VAF 34/381 reads (9%) | catalogued as COSV58263514; called by muse, mutect2
- GRK1 | c.51C>T p.A17= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs779199924, COSV59552871; called by muse, mutect2, varscan2
- LMAN2 | c.381C>T p.N127= | Silent (SNP) | VAF 111/285 reads (39%) | catalogued as rs372993074; called by muse, mutect2, varscan2
- LRRK1 | c.2976C>T p.P992= | Silent (SNP) | VAF 72/139 reads (52%) | catalogued as COSV52612912; called by muse, mutect2, varscan2
- PCIF1 | c.786C>T p.S262= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV65026252; called by muse, mutect2
- PGAP4 | c.693C>T p.R231= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as rs756188298, COSV66387748; called by muse, mutect2, varscan2
- RMND5A | c.702G>A p.L234= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as COSV52153852; called by muse, mutect2, varscan2
- SLC39A12 | c.942G>A p.R314= | Silent (SNP) | VAF 69/86 reads (80%) | catalogued as COSV66198569, COSV66200422; called by muse, mutect2, varscan2
- SMC2 | c.2145A>G p.L715= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV53958701; called by muse, mutect2, varscan2
- STK10 | c.2733G>A p.K911= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as COSV51574401; called by muse, mutect2, varscan2
- TLL1 | c.1233C>T p.D411= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs764830976, COSV50261673; called by muse, mutect2, varscan2
